Gene-level copy-number profile of tumor specimen TCGA-EE-A2GP-06A from TCGA case TCGA-EE-A2GP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.5 years (29,759 days).
Specimen TCGA-EE-A2GP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ae2bb8a5-019f-46e5-8d93-a2066dfd00c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2GP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2aec3ac1-2d48-420d-9014-62e8f68a9c02

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,015; copy number 2: 17,066; copy number 3: 18,704; copy number 4: 17,567; copy number 5: 3,932; copy number 6: 530; copy number 7: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2GP-06A-11D-A191-01): tumor purity 0.63, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:20,318,119–20,354,387, 5 genes, copy number 7: AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 2,015. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
